TARGET case TARGET-40-NAAFJP — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f523ae11-b38a-5b3c-a657-5e746e9971b1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 17.4 years (6,373 days); Year of diagnosis: 2008; Metastasis at diagnosis: No Metastasis; Days to last follow up: 2,714 days (7.4 years).
   Pathology details: Necrosis percent: 95.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Etoposide.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (2 entries)
- Days to follow up: 2,675 days (7.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,675 days (7.3 years); Days to first event: 2,675 days (7.3 years); First event: Relapse.
- Days to follow up: 2,714 days (7.4 years); Year of follow up: 2016.

Biospecimens (1 sample)
- Sample TARGET-40-NAAFJP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAFJP-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 97
- % Non Tumor Nuclei: Top from Biopsy: 3
- % Cellular Tumor: Top from Biopsy: 93
- % Normal: Top from Biopsy: 2
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 5
- % Tumor Nuclei: Bottom from Biopsy: 80
- % Non Tumor Nuclei: Bottom from Biopsy: 20
- % Cellular Tumor: Bottom from Biopsy: 60
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 40
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2714
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Pelvis
- Specific tumor site: Pubic Ramus
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Lung
- Histologic response: Stage 3/4 (91-100 % necrosis)
- Relapse Type: Systemic
- Therapy: MTX, Adria, Cis, Ifos, VP-16
